Somatic mutation profile of tumor specimen MMRF_1433_2_BM_CD138pos (aliquot MMRF_1433_2_BM_CD138pos_T1_KHS5U_L13754) from MMRF case MMRF_1433, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.8 years (20,373 days).
Specimen MMRF_1433_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b86adfd0-08ea-457a-a712-56bc77555b34.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1433_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1433_1_PB_Whole_C2_KAS5U_L01389; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d75c4994-ec21-45bc-899e-abe0e8ac50bb

The open-access MAF lists 174 somatic variants for this specimen: 71 protein-altering or splice-affecting, 24 silent, 79 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, 3'UTR 41, Silent 24, Intron 17, 5'UTR 12, 3'Flank 5, Frame Shift Del 5, 5'Flank 4, Splice Site 1, Nonsense Mutation 1, In Frame Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA5 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.779); catalogued as COSV67016767; called by muse, mutect2, varscan2
- ACAP1 | c.440G>T p.R147L | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV50134614; called by muse, mutect2, varscan2
- ATM | c.8402G>A p.C2801Y | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53745608; called by muse, mutect2, varscan2
- BMP15 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782668766; called by muse, mutect2
- ELN | c.1969G>A p.A657T (on ENST00000320399 / NM_001278939.1; = p.A624T on NM_000501.4) | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as rs782693956; called by muse, mutect2
- IGLV3-9 | c.82T>C p.S28P | Missense Mutation (SNP) | VAF 71/197 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs1187894997; called by muse, varscan2
- KLHL29 | c.1094G>A p.S365N | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs1349173171; called by muse, mutect2, varscan2
- NFE2L3 | c.1861_1862del p.K621Efs*7 | Frame Shift Del (DEL) | VAF 17/110 reads (15%) | catalogued as rs777869574, COSV50227502; called by mutect2, pindel, varscan2
- OBSCN | c.3814G>T p.A1272S | Missense Mutation (SNP) | VAF 112/296 reads (38%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.644); catalogued as COSV52816512; called by muse, varscan2
- PADI6 | c.1090T>C p.C364R | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs770181514; called by muse, mutect2, varscan2
- PLA2G4C | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV62788171; called by muse, mutect2, varscan2
- PPP1R3A | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52881558; called by muse, mutect2, varscan2
- PRKD2 | c.1903T>A p.L635M | Missense Mutation (SNP) | VAF 78/211 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99354464; called by muse, mutect2, varscan2
- SEPTIN9 | c.292C>T p.P98S (on ENST00000427177 / NM_001113491.2; = p.P80S on NM_006640.4) | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); catalogued as rs866528394, COSV61202801; called by muse, mutect2, varscan2
- SLC43A2 | c.1405G>A p.G469R | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100025245; called by muse, mutect2, varscan2
- SYT16 | c.1487C>T p.S496L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as COSV70859382; called by muse, mutect2, varscan2
- TRDN | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.395); catalogued as COSV62113491; called by muse, mutect2, varscan2
- ZER1 | c.1198G>T p.A400S | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1465125881; called by muse, mutect2, varscan2
- ABCC9 | c.3614A>G p.N1205S | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ACSM2B | c.132T>G p.F44L | Missense Mutation (SNP) | VAF 11/238 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- ADAM15 | c.143T>G p.V48G | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- ADAM29 | c.2462A>T p.*821Lext*61 | Nonstop Mutation (SNP) | VAF 93/326 reads (29%) | called by muse, mutect2, varscan2
- ADAMTS14 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- ADAMTS3 | c.1856A>C p.Q619P | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- AGL | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- ARVCF | c.579del p.E194Sfs*128 | Frame Shift Del (DEL) | VAF 35/76 reads (46%) | called by mutect2, pindel, varscan2
- BRINP2 | c.1954T>A p.S652T | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT tolerated (0.86); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC40 | c.2506C>G p.L836V | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CELSR2 | c.7535G>C p.W2512S | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHIC2 | c.159_161del p.S54del | In Frame Del (DEL) | VAF 12/58 reads (21%) | called by pindel, varscan2
- CHMP1B | c.488A>G p.D163G | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- CHST4 | c.339G>T p.M113I | Missense Mutation (SNP) | VAF 16/434 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.088); called by muse, mutect2
- CLVS2 | c.710A>G p.H237R | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- COL20A1 | c.2910C>G p.F970L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CREBRF | c.1006A>G p.N336D | Missense Mutation (SNP) | VAF 71/192 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- DIS3 | c.784A>C p.T262P | Missense Mutation (SNP) | VAF 57/84 reads (68%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- EHBP1 | c.1147_1151delinsG p.N383Gfs*2 | Frame Shift Del (DEL) | VAF 58/152 reads (38%) | called by pindel, varscan2*
- FAM111B | c.1979A>T p.K660I | Missense Mutation (SNP) | VAF 81/231 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- FAT1 | c.7145A>C p.D2382A | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FREM3 | c.28G>C p.G10R | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- GCC2 | c.2381A>T p.N794I | Missense Mutation (SNP) | VAF 51/197 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- HABP2 | c.1432A>C p.N478H | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HHLA1 | c.1528G>T p.V510L | Missense Mutation (SNP) | VAF 8/282 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, mutect2
- HNRNPC | c.230G>A p.G77D | Missense Mutation (SNP) | VAF 70/294 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- INO80D | c.2188G>T p.E730* | Nonsense Mutation (SNP) | VAF 50/148 reads (34%) | called by muse, mutect2, varscan2
- KIF4B | c.2383C>T p.L795F | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2
- KRT84 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- KRT85 | c.58T>C p.S20P | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- MIXL1 | c.389T>C p.I130T | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MN1 | c.3374G>A p.G1125D | Missense Mutation (SNP) | VAF 56/195 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- MSR1 | c.643T>A p.L215I | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NLGN1 | c.1762A>C p.I588L | Missense Mutation (SNP) | VAF 101/282 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- PEX11A | c.372_375del p.H125Tfs*8 | Frame Shift Del (DEL) | VAF 127/349 reads (36%) | called by mutect2, pindel, varscan2
- PTPN23 | c.4837G>A p.G1613R | Missense Mutation (SNP) | VAF 125/369 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- PTPRK | c.3020G>C p.G1007A (on ENST00000368215 / NM_001291984.2; = p.G1008A on NM_002844.4) | Missense Mutation (SNP) | VAF 82/255 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- RICTOR | c.2350C>T p.L784F | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- RPL5 | c.73+5_73+24del p.X25_splice | Splice Site (DEL) | VAF 28/127 reads (22%) | called by mutect2, pindel, varscan2
- SEC62 | c.764T>C p.I255T | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- SKOR2 | c.1945T>C p.S649P | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- SLC12A6 | c.164G>C p.S55T | Missense Mutation (SNP) | VAF 90/433 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC4A8 | c.2453G>C p.G818A | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TGFBR3 | c.961C>G p.P321A | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM121 | c.350T>C p.L117P | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM184A | c.603C>G p.I201M | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.714); called by muse, mutect2
- TMIGD3 | c.529G>A p.G177R (on ENST00000369717 / NM_001081976.2; = p.G258R on NM_020683.7) | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRAM1L1 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIM47 | c.788A>C p.E263A | Missense Mutation (SNP) | VAF 52/189 reads (28%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TUBD1 | c.376del p.E126Kfs*14 | Frame Shift Del (DEL) | VAF 86/221 reads (39%) | called by mutect2, pindel, varscan2
- UBL7 | c.317A>C p.K106T | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2
- ZNF383 | c.1119G>T p.K373N | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF585B | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARL5B | c.426C>T p.L142= | Silent (SNP) | VAF 6/107 reads (6%) | called by muse, mutect2
- BIRC7 | c.45G>A p.Q15= | Silent (SNP) | VAF 29/123 reads (24%) | called by muse, mutect2, varscan2
- CD84 | c.558C>T p.D186= | Silent (SNP) | VAF 7/188 reads (4%) | called by muse, mutect2
- CLGN | c.333G>A p.L111= | Silent (SNP) | VAF 17/66 reads (26%) | called by muse, mutect2, varscan2
- DHRS4 | c.33C>A p.A11= | Silent (SNP) | VAF 39/101 reads (39%) | catalogued as COSV57481734; called by muse, mutect2, varscan2
- EMB | c.117G>A p.S39= | Silent (SNP) | VAF 78/261 reads (30%) | catalogued as rs112602380, COSV57482377; called by muse, mutect2, varscan2
- IL18R1 | c.732G>A p.E244= | Silent (SNP) | VAF 71/247 reads (29%) | catalogued as rs759376271; called by muse, mutect2, varscan2
- KLK6 | c.327G>T p.L109= | Silent (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- LCOR | c.381T>G p.G127= | Silent (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- LIMD2 | c.18A>C p.G6= | Silent (SNP) | VAF 26/85 reads (31%) | called by muse, mutect2, varscan2
- MUC17 | c.1812T>C p.S604= | Silent (SNP) | VAF 135/532 reads (25%) | catalogued as rs924264870; called by muse, mutect2, varscan2
- NECTIN3 | c.117G>A p.L39= | Silent (SNP) | VAF 53/129 reads (41%) | catalogued as rs1452881807; called by muse, mutect2, varscan2
- PIF1 | c.417G>A p.L139= | Silent (SNP) | VAF 27/84 reads (32%) | called by muse, mutect2, varscan2
- SLC7A9 | c.105C>T p.G35= | Silent (SNP) | VAF 44/158 reads (28%) | called by muse, mutect2, varscan2
- SOX5 | c.975T>C p.A325= | Silent (SNP) | VAF 11/112 reads (10%) | called by muse, mutect2
- TBC1D10B | c.198G>C p.S66= | Silent (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- THSD7A | c.3663C>T p.H1221= | Silent (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- TLR7 | c.2337T>C p.L779= | Silent (SNP) | VAF 93/116 reads (80%) | called by muse, mutect2, varscan2
- TUBGCP4 | c.1791C>G p.V597= (on ENST00000260383 / NM_001286414.3; = p.V596= on NM_014444.5) | Silent (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
- USP3 | c.1428A>C p.A476= | Silent (SNP) | VAF 16/127 reads (13%) | catalogued as rs1486881516; called by muse, mutect2, varscan2
- YEATS2 | c.2088A>G p.G696= | Silent (SNP) | VAF 36/118 reads (31%) | called by muse, mutect2, varscan2
- ZFP91 | c.321C>A p.G107= | Silent (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
- ZNF503 | c.1923G>A p.S641= | Silent (SNP) | VAF 11/45 reads (24%) | called by muse, mutect2, varscan2
- ZSCAN18 | c.1284G>A p.L428= | Silent (SNP) | VAF 29/110 reads (26%) | catalogued as rs750087617; called by muse, mutect2, varscan2
- AC011503.1 | n.467+8549C>A | Intron (SNP) | VAF 31/119 reads (26%) | called by muse, mutect2, varscan2
- ACTG1 | c.-134G>T | 5'UTR (SNP) | VAF 38/69 reads (55%) | called by muse, mutect2, varscan2
- ADRA2A | c.-305A>G | 5'UTR (SNP) | VAF 33/81 reads (41%) | called by muse, mutect2, varscan2
- AK9 | c.*358A>G | 3'UTR (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- ALDH3A1 | c.*74G>A | 3'UTR (SNP) | VAF 14/79 reads (18%) | catalogued as rs751526560; called by muse, mutect2, varscan2
- ARHGAP42 | c.*3849G>C | 3'UTR (SNP) | VAF 53/203 reads (26%) | catalogued as COSV53972583; called by muse, mutect2, varscan2
- ATP2B4 | c.*784C>T | 3'UTR (SNP) | VAF 17/131 reads (13%) | called by muse, mutect2, varscan2
- BHLHE40 | c.*1383G>A | 3'UTR (SNP) | VAF 7/26 reads (27%) | catalogued as rs751178895; called by muse, mutect2, varscan2
- BIRC3 | c.*2122C>G | 3'UTR (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
- CACNG2 | c.-452C>A | 5'UTR (SNP) | VAF 23/102 reads (23%) | called by muse, mutect2, varscan2
- CD19 | c.1085-31T>A | Intron (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- CHRM3 | c.*212C>T | 3'UTR (SNP) | VAF 13/58 reads (22%) | catalogued as rs1269912531, COSV55093271; called by muse, mutect2, varscan2
- CPN2 | c.*124C>T | 3'UTR (SNP) | VAF 19/82 reads (23%) | called by muse, mutect2, varscan2
- DIRAS2 | c.*806G>T | 3'UTR (SNP) | VAF 37/72 reads (51%) | called by muse, mutect2, varscan2
- DPP6 | c.-157C>G | 5'UTR (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- EBF2 | c.-264G>A | 5'UTR (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- EML3 | c.22+188C>A | Intron (SNP) | VAF 17/35 reads (49%) | called by muse, mutect2, varscan2
- EPHB6 | c.1751-182_1751-133del | Intron (DEL) | VAF 3/15 reads (20%) | called by muse*, mutect2
- EXOC6B | c.1980+2765A>G | Intron (SNP) | VAF 6/93 reads (6%) | called by muse, mutect2
- FBRS | chr16:30661321 T>A | 5'Flank (SNP) | VAF 30/119 reads (25%) | called by muse, mutect2, varscan2
- GAD1 | c.*737G>A | 3'UTR (SNP) | VAF 11/51 reads (22%) | catalogued as rs943528474; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GCNT2 | c.*433A>C | 3'UTR (SNP) | VAF 29/124 reads (23%) | catalogued as rs1202780095; called by muse, mutect2, varscan2
- GORASP2 | c.*671T>G | 3'UTR (SNP) | VAF 31/72 reads (43%) | called by muse, mutect2, varscan2
- GPR182 | c.*276A>C | 3'UTR (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2, varscan2
- GPR75 | c.-218C>T | 5'UTR (SNP) | VAF 32/68 reads (47%) | catalogued as rs1317788376; called by muse, mutect2, varscan2
- H2AZ2 | chr7:44828530 T>G | 3'Flank (SNP) | VAF 26/85 reads (31%) | called by muse, mutect2, varscan2
- INTS3 | c.-54T>G | 5'UTR (SNP) | VAF 43/62 reads (69%) | called by muse, mutect2, varscan2
- JPH1 | c.-52G>A | 5'UTR (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- KCNJ6 | c.26-2086A>G | Intron (SNP) | VAF 21/58 reads (36%) | called by muse, mutect2, varscan2
- LIMS2 | c.*597C>T | 3'UTR (SNP) | VAF 55/189 reads (29%) | catalogued as rs1344423313; called by muse, mutect2, varscan2
- LINS1 | c.*1400G>A | 3'UTR (SNP) | VAF 24/96 reads (25%) | called by muse, mutect2, varscan2
- MAGI2 | c.*2101G>A | 3'UTR (SNP) | VAF 24/62 reads (39%) | catalogued as rs1030328624; called by muse, mutect2, varscan2
- MSH6 | chr2:47807434 T>C | 3'Flank (SNP) | VAF 44/88 reads (50%) | called by muse, mutect2, varscan2
- MXD3 | c.177-37T>C | Intron (SNP) | VAF 35/99 reads (35%) | called by muse, mutect2, varscan2
- NAF1 | chr4:163126951 A>C | 3'Flank (SNP) | VAF 24/71 reads (34%) | called by muse, mutect2, varscan2
- NR2F1 | c.-310G>A | 5'UTR (SNP) | VAF 26/91 reads (29%) | called by muse, mutect2, varscan2
- OCLN | c.*641G>A | 3'UTR (SNP) | VAF 30/67 reads (45%) | called by muse, mutect2, varscan2
- OSBP | c.*1295C>G | 3'UTR (SNP) | VAF 30/88 reads (34%) | called by muse, mutect2, varscan2
- OTUD4 | c.*3681C>T | 3'UTR (SNP) | VAF 64/163 reads (39%) | called by muse, mutect2, varscan2
- PADI2 | c.*1183G>A | 3'UTR (SNP) | VAF 13/67 reads (19%) | called by muse, mutect2, varscan2
- PARK7 | c.322+203G>T | Intron (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- PI4K2A | c.-27C>G | 5'UTR (SNP) | VAF 12/31 reads (39%) | called by muse, varscan2
- PLEKHG5 | c.-54+238C>G | Intron (SNP) | VAF 21/66 reads (32%) | called by muse, mutect2, varscan2
- PPARGC1B | c.*2918_*2940del | 3'UTR (DEL) | VAF 28/146 reads (19%) | called by mutect2, pindel*
- PPM1L | c.575-43241_575-43240del | Intron (DEL) | VAF 32/168 reads (19%) | called by mutect2, pindel, varscan2
- PRKG1 | c.*3682G>A | 3'UTR (SNP) | VAF 29/59 reads (49%) | called by muse, mutect2, varscan2
- PRPS1 | c.*228G>A | 3'UTR (SNP) | VAF 41/68 reads (60%) | called by muse, mutect2, varscan2
- PSTPIP2 | c.213-65C>A | Intron (SNP) | VAF 39/99 reads (39%) | called by muse, mutect2, varscan2
- RAB5IF | c.*68A>C | 3'UTR (SNP) | VAF 24/533 reads (5%) | called by muse, mutect2
- RFPL4B | c.*628T>A | 3'UTR (SNP) | VAF 47/112 reads (42%) | called by muse, mutect2, varscan2
- RFX7 | c.*2364T>C | 3'UTR (SNP) | VAF 37/97 reads (38%) | called by muse, mutect2, varscan2
- RNF213 | c.10304-356G>A | Intron (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- RPL24 | chr3:101686827 G>A | 5'Flank (SNP) | VAF 50/167 reads (30%) | catalogued as rs1051068409; called by muse, mutect2, varscan2
- RPL24 | chr3:101686828 C>T | 5'Flank (SNP) | VAF 48/163 reads (29%) | called by muse, mutect2, varscan2
- SEC61A1 | c.777+75C>G | Intron (SNP) | VAF 53/291 reads (18%) | called by muse, mutect2, varscan2
- SERINC2 | chr1:31410402 G>A | 5'Flank (SNP) | VAF 3/33 reads (9%) | catalogued as rs540475475; called by muse, mutect2
- SLC16A7 | c.*2579T>A | 3'UTR (SNP) | VAF 17/85 reads (20%) | called by muse, mutect2, varscan2
- SLC19A1 | c.*1016G>A | 3'UTR (SNP) | VAF 47/152 reads (31%) | called by muse, mutect2, varscan2
- SLC45A4 | c.*3750C>G | 3'UTR (SNP) | VAF 80/194 reads (41%) | called by muse, mutect2, varscan2
- SLC6A2 | c.*1208A>G | 3'UTR (SNP) | VAF 16/72 reads (22%) | called by muse, mutect2, varscan2
- SLCO4A1 | c.*318C>T | 3'UTR (SNP) | VAF 36/102 reads (35%) | catalogued as rs926588686; called by muse, mutect2, varscan2
- SLCO5A1 | c.-160C>T | 5'UTR (SNP) | VAF 39/120 reads (33%) | called by muse, mutect2, varscan2
- SNU13 | c.*18C>T | 3'UTR (SNP) | VAF 14/29 reads (48%) | catalogued as rs369403795; called by muse, mutect2, varscan2
- SNX13 | c.*363G>T | 3'UTR (SNP) | VAF 35/81 reads (43%) | called by muse, mutect2, varscan2
- SNX3 | c.*684T>G | 3'UTR (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- STK25 | c.*1209C>T | 3'UTR (SNP) | VAF 44/182 reads (24%) | called by muse, mutect2, varscan2
- SZT2 | c.499-4717A>C | Intron (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2
- THAP1 | c.*1000T>C | 3'UTR (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- THUMPD2 | c.672+540C>T | Intron (SNP) | VAF 72/190 reads (38%) | catalogued as rs1396965157; called by muse, mutect2, varscan2
- TMEM144 | c.109+550T>C | Intron (SNP) | VAF 43/103 reads (42%) | called by muse, mutect2, varscan2
- TMEM201 | c.1160+1502G>A | Intron (SNP) | VAF 33/135 reads (24%) | called by muse, mutect2, varscan2
- TNFRSF19 | chr13:23674032 T>A | 3'Flank (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- VEZF1 | c.*83C>T | 3'UTR (SNP) | VAF 9/26 reads (35%) | called by mutect2, varscan2
- VGLL3 | c.*5152T>A | 3'UTR (SNP) | VAF 20/84 reads (24%) | called by muse, mutect2, varscan2
- WDR33 | c.*1261T>G | 3'UTR (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- WDR86 | c.-226G>A | 5'UTR (SNP) | VAF 38/102 reads (37%) | catalogued as rs949454830; called by muse, mutect2, varscan2
- XRN1 | c.*3680C>T | 3'UTR (SNP) | VAF 27/64 reads (42%) | called by muse, mutect2, varscan2
- ZPLD1 | chr3:102478266 T>C | 3'Flank (SNP) | VAF 20/59 reads (34%) | called by muse, mutect2, varscan2
- ZZZ3 | c.*323G>T | 3'UTR (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
